Surgical pathology report (de-identified scan), TCGA case TCGA-XM-AAZ3, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-AAZ3-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Thoracic
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] M Date of Receipt:
Physician: [REDACTED] Date of Report:
CC: [REDACTED]

....

Clinical Diagnosis & History:
male with left anterior lung mass, biopsy shows spindle
cell neoplasm.

Specimens Submitted:
1: Left anterior mediastinal mass (fs)
2: Portion left sixth rib
3: Left anterior mediastinal lymph node

DIAGNOSIS:

1. Left anterior mediastinal mass (fs):
- Thymoma, type AB.
- The tumor measures 16 x 14.5 x 9 .2 cm in greatest dimension.
- The tumor invades focally through the capsule into the adipose tissue.
- The surgical resection margin is free of tumor.
2. Portion left sixth rib:
- Unremarkable bony trabeculae and bone marrow with intact trilineage hematopoiesis.
3. Left anterior mediastinal lymph node:
- Benign fibroadipose and vascular tissue.
- No lymph node identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for frozen section, labeled "left anterior mediastinal mass." It consists of an encapsulated tan-pink mass that measures 16 x 14.5 x 9 .2 cm and weighs 764.8 gm. The outer surface is relatively smooth with adherent adipose tissue and is inked in black. The

** Continued on next page **

ICD-O-3

Thymoma, type AB, malignant
8582/3

Sub Anterior mediastinum

9/3/12/14 (38.1)

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Accession [REDACTED]

Physician: [REDACTED]

Service: Thoracic

Date of Report: [REDACTED]

----- Page 2 of 3

specimen is bivalved and the cut section reveals a tan pink soft fleshy, solid, and partially cystic and variegated surface. The cystic areas contain tan to brown fluid. There are areas of necrosis and hemorrhage at the periphery of the tumor. Representative sections are submitted for TPS and permanent section. Photographs are taken.

Summary of sections:

FSC - frozen section control

TC-tumor with inked capsule

T-tumor

2. Received in formalin and labeled "portion of left sixth rib" is a portion of rib measuring 2.1cmx1.5cmx0.5cm Representative section submitted with previous decalcification.

U-- undesignated

3. The specimen is received in formalin, labeled "left anterior mediastinal lymph node", and consists of a 1.2 x 0.5 x 0.4cm fragment of tan soft tissue. No lymph nodes are identified. The specimen is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Left anterior mediastinal mass (fs)

Block	Sect.	Site	PCs
1		FSC	2
8		T	8
10		TC	10

Part 2: Portion left sixth rib

Block	Sect.	Site	PCs
1		U	1

Part 3: Left anterior mediastinal lymph node

Block	Sect.	Site	PCs
1		U	1

Intraoperative Consultation:

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT
Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: Thoracic
Date of Report:

----- Page 3 of 3
Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Left anterior mediastinal mass (fs): Spindle cell tumor. Favor thymoma
Permanent Diagnosis: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Left anterior mediastinal mass (fs): Spindle cell tumor. Favor thymoma
Permanent Diagnosis: Same

** End of Report **

Source: NCI Genomic Data Commons file aa6922c3-67d1-4012-9aab-63c05ac761f1 (TCGA-XM-AAZ3.E74967BF-0603-42BC-A06B-8DFAD520B163.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).